Somatic mutation profile of tumor specimen ALCH-B2BA-TTP1-A (aliquot ALCH-B2BA-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2BA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.4 years (21,678 days).
Specimen ALCH-B2BA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0c27782-8bfe-49fa-bff8-59f4e29ad817.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2BA-NB1-A (Blood Derived Normal), aliquot ALCH-B2BA-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/786a1bdb-0f7e-48a2-bb11-de988f53bba0

The open-access MAF lists 435 somatic variants for this specimen: 281 protein-altering or splice-affecting, 102 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 242, Silent 102, Intron 25, Nonsense Mutation 17, RNA 13, Splice Region 8, Frame Shift Del 7, 3'UTR 7, 5'Flank 5, Splice Site 5, 5'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 48/169 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519977, COSV52671863, COSV52706449, COSV52741627, COSV52827803; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AADACL3 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1433211576, COSV60198385; called by muse, mutect2, varscan2
- AADACL4 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 40/439 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as rs1257201912, COSV66105972; called by muse, mutect2
- ADD1 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 54/476 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs748552349; called by muse, mutect2, varscan2
- ADGRV1 | c.15407C>T p.S5136F | Missense Mutation (SNP) | VAF 78/900 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs867467575, COSV67987841, COSV67994326; called by muse, mutect2
- AL645922.1 | c.1840G>T p.G614W | Missense Mutation (SNP) | VAF 87/447 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54960947; called by muse, mutect2, varscan2
- ALPK3 | c.2954G>A p.G985E | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs376664318; called by muse, mutect2, varscan2
- AMDHD2 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 13/289 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53551223; called by muse, mutect2
- ARHGEF6 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV51687630; called by muse, mutect2, varscan2
- ARMC5 | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs181967284, COSV51659719; called by muse, mutect2, varscan2
- ASTN1 | c.1342C>A p.L448I | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56061226, COSV99921168; called by muse, mutect2, varscan2
- BPIFA2 | c.746T>A p.I249N | Missense Mutation (SNP) | VAF 125/407 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as rs1555790979; called by muse, mutect2, varscan2
- BRDT | c.2185G>T p.V729L | Missense Mutation (SNP) | VAF 57/325 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV100746624; called by muse, mutect2, varscan2
- BTBD11 | c.2407G>A p.A803T (on ENST00000280758 / NM_001018072.2; = p.A340T on NM_001017523.2) | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as rs373478884; called by muse, mutect2, varscan2
- CACNA2D3 | c.1739C>T p.T580M | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376151290; called by muse, mutect2, varscan2
- CAD | c.5008G>A p.V1670M | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs377126982; called by muse, mutect2, varscan2
- CAVIN4 | c.689G>T p.R230M | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199804309; called by muse, mutect2, varscan2
- CAVIN4 | c.690G>T p.R230S | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56867942; called by mutect2, varscan2
- CBLIF | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 66/715 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs533802342, COSV57238204; called by muse, mutect2
- CCDC85A | c.1452G>T p.P484= | Splice Region (SNP) | VAF 56/194 reads (29%) | catalogued as COSV68149492; called by muse, mutect2, varscan2
- CD96 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 90/613 reads (15%) | catalogued as COSV99343632; called by muse, mutect2, varscan2
- CERKL | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV59204230; called by muse, mutect2, varscan2
- CNBD1 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 53/389 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV73073294; called by muse, mutect2, varscan2
- CRHBP | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs1188149010; called by muse, mutect2, varscan2
- CSMD3 | c.6287C>G p.P2096R (on ENST00000297405 / NM_001363185.1; = p.P1992R on NM_052900.3) | Missense Mutation (SNP) | VAF 187/684 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as COSV52265807; called by muse, mutect2, varscan2
- CSNK1D | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.116); catalogued as rs1322411760, COSV53926303; called by muse, mutect2, varscan2
- CTNNA2 | c.2485G>C p.D829H | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.353); catalogued as rs1407504349, COSV58177842; called by muse, mutect2, varscan2
- DHX35 | c.1936G>T p.A646S | Missense Mutation (SNP) | VAF 175/612 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as rs748771313; called by muse, mutect2, varscan2
- DNAH5 | c.1558A>G p.K520E | Missense Mutation (SNP) | VAF 321/896 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV54255025; called by muse, mutect2, varscan2
- DNAH6 | c.622G>T p.V208L | Missense Mutation (SNP) | VAF 94/301 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV52869913; called by muse, mutect2, varscan2
- DSP | c.5557C>G p.L1853V | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.787); catalogued as rs1239776217; called by muse, mutect2, varscan2
- DZIP1 | c.2450C>T p.A817V (on ENST00000347108; = p.A798V on NM_014934.5) | Missense Mutation (SNP) | VAF 35/523 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs149105659; called by muse, mutect2
- DZIP1L | c.2200C>G p.L734V | Missense Mutation (SNP) | VAF 190/535 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV100551641; called by muse, mutect2, varscan2
- EPHA5 | c.3087G>C p.Q1029H | Missense Mutation (SNP) | VAF 27/437 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99899626; called by muse, mutect2
- EPS8L2 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs1380250447, COSV59349357; called by muse, mutect2, varscan2
- ERICH3 | c.4216G>A p.E1406K | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV58602631; called by muse, mutect2, varscan2
- F9 | c.724G>T p.V242F | Missense Mutation (SNP) | VAF 141/429 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM125296; called by muse, mutect2, varscan2
- FAM135B | c.2620G>T p.E874* | Nonsense Mutation (SNP) | VAF 107/726 reads (15%) | catalogued as COSV52704758; called by muse, mutect2, varscan2
- FAM237A | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as rs750234006, COSV69304994, COSV69305367; called by muse, mutect2, varscan2
- FCRL4 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 116/586 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.748); catalogued as rs754720966; called by muse, mutect2, varscan2
- FHOD3 | c.2953G>T p.A985S (on ENST00000359247 / NM_001281739.3; = p.A1002S on NM_025135.5) | Missense Mutation (SNP) | VAF 123/410 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57165833; called by muse, mutect2, varscan2
- FMN2 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV100143184; called by muse, mutect2, varscan2
- FOXN2 | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 111/476 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100489079; called by muse, mutect2, varscan2
- GFPT2 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780878334, COSV53814383; called by muse, mutect2, varscan2
- GIMAP2 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs535499408, COSV99785211; called by muse, mutect2, varscan2
- GMPR | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs770523911, COSV52474674, COSV99440268; called by muse, mutect2, varscan2
- GPR141 | c.131A>T p.K44I | Missense Mutation (SNP) | VAF 201/549 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV57734529; called by muse, mutect2, varscan2
- HAS1 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 33/342 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs749903902; called by muse, mutect2
- HLA-DRB1 | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 215/1497 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778903456; called by muse, varscan2
- HNF1A | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99983088; called by muse, mutect2, varscan2
- HNF1A | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776327501, COSV57459833; called by muse, mutect2, varscan2
- HOXC13 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99673657; called by muse, mutect2, varscan2
- IFIT1 | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 110/303 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs973342147; called by muse, mutect2, varscan2
- IL20RA | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs757869709; called by muse, mutect2
- INHBA | c.468G>T p.W156C | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54221838; called by muse, mutect2, varscan2
- INHBA | c.467G>C p.W156S | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54224668; called by muse, mutect2, varscan2
- IRAG2 | c.2843C>G p.T948R | Missense Mutation (SNP) | VAF 30/687 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.538); catalogued as rs370845805; called by muse, mutect2
- KRTAP4-8 | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 123/575 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs538021486; called by muse, mutect2, varscan2
- LIN52 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 38/675 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs1227181611, COSV73465917; called by muse, mutect2
- LMO4 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.169); catalogued as COSV65170590; called by muse, mutect2, varscan2
- LMOD1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs777813811; called by muse, mutect2, varscan2
- LRIT3 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs1167375295; called by muse, mutect2, varscan2
- LRP1B | c.3599C>A p.P1200H | Missense Mutation (SNP) | VAF 143/547 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV101257887; called by muse, mutect2, varscan2
- LRRC7 | c.2759C>A p.T920N (on ENST00000651989 / NM_001370785.2; = p.T887N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/558 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.343); catalogued as COSV50448278; called by muse, mutect2, varscan2
- LRRTM4 | c.1286G>T p.S429I | Missense Mutation (SNP) | VAF 94/372 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV69141380; called by muse, mutect2, varscan2
- MAP2 | c.4249G>T p.A1417S | Missense Mutation (SNP) | VAF 161/569 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.597); catalogued as COSV99557386; called by muse, mutect2, varscan2
- MORC1 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 51/434 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV99227589; called by muse, mutect2, varscan2
- NBAS | c.2885C>T p.A962V | Missense Mutation (SNP) | VAF 136/545 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55731329; called by muse, varscan2
- NECAB1 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 43/489 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV101341046; called by muse, mutect2
- NLGN1 | c.223G>T p.G75W | Missense Mutation (SNP) | VAF 66/715 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765261134, COSV100848677, COSV64340835; called by muse, mutect2
- OR13C8 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1262160225, COSV100622961; called by muse, mutect2, varscan2
- OR4P4 | c.143C>A p.T48K | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.738); catalogued as COSV58921374; called by muse, mutect2, varscan2
- OR51T1 | c.941C>A p.S314* | Nonsense Mutation (SNP) | VAF 52/208 reads (25%) | catalogued as COSV59025370; called by muse, mutect2, varscan2
- OR8H2 | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV100542288; called by muse, mutect2, varscan2
- PCDHA7 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 148/495 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs558922738, COSV100971907; called by muse, mutect2, varscan2
- PCSK2 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 120/363 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52729214; called by muse, mutect2, varscan2
- PLEKHA6 | c.1885G>T p.D629Y | Missense Mutation (SNP) | VAF 66/346 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55332483; called by muse, mutect2, varscan2
- POU6F2 | c.1288C>G p.L430V | Missense Mutation (SNP) | VAF 57/642 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.294); catalogued as rs1380574751, COSV68877654; called by muse, mutect2
- PTEN | c.762del p.V255* | Frame Shift Del (DEL) | VAF 334/944 reads (35%) | catalogued as COSV64289952, COSV64311573; called by mutect2, pindel, varscan2
- PTPN3 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776045957, COSV52704644; called by muse, mutect2, varscan2
- PWWP3A | c.172G>A p.E58K (on ENST00000627377; = p.E57K on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as rs1452167149, COSV60901913; called by muse, mutect2, varscan2
- PXN | c.1737G>T p.K579N (on ENST00000228307 / NM_001080855.3; = p.K545N on NM_002859.4) | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57217280; called by muse, mutect2, varscan2
- PXN | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs187461916; called by muse, mutect2, varscan2
- RANBP17 | c.834A>G p.L278= | Splice Region (SNP) | VAF 63/242 reads (26%) | catalogued as rs770212182; called by muse, mutect2, varscan2
- RELN | c.1231C>G p.L411V | Missense Mutation (SNP) | VAF 209/1969 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as CM152079, COSV58989985; called by muse, mutect2, varscan2
- RNF139 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 67/974 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777779465, COSV52678520; called by muse, mutect2
- RSBN1 | c.2182C>G p.R728G | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV99793515; called by muse, mutect2, varscan2
- RYR1 | c.4237G>A p.D1413N | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs139142846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.6375C>A p.H2125Q | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as rs768273866; called by muse, mutect2, varscan2
- RYR1 | c.12676G>C p.E4226Q | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV62096875, COSV62110603; called by muse, mutect2, varscan2
- RYR2 | c.6145G>T p.E2049* | Nonsense Mutation (SNP) | VAF 61/303 reads (20%) | catalogued as COSV63661105; called by muse, mutect2, varscan2
- SEPTIN14 | c.497C>A p.S166* | Nonsense Mutation (SNP) | VAF 50/378 reads (13%) | catalogued as COSV66429188; called by muse, mutect2, varscan2
- SLC25A10 | c.724G>C p.V242L | Missense Mutation (SNP) | VAF 103/232 reads (44%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV58972319; called by muse, mutect2, varscan2
- SLC2A14 | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV61588339; called by muse, varscan2
- SPTBN4 | c.5524G>A p.D1842N | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767195625; called by muse, mutect2, varscan2
- ST6GAL2 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 33/105 reads (31%) | catalogued as COSV64528114; called by muse, mutect2, varscan2
- STRN4 | c.1864G>T p.V622F | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV54418654; called by muse, mutect2, varscan2
- TASP1 | c.187C>G p.H63D | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV61814704; called by muse, mutect2
- TRAV8-4 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 134/520 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1469344582; called by muse, mutect2, varscan2
- TRIM55 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 107/618 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as rs754147349, COSV52545616; called by muse, mutect2, varscan2
- UGT3A1 | c.849G>T p.L283F | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.308); catalogued as COSV99955296; called by muse, mutect2
- ZDBF2 | c.5795G>T p.R1932L | Missense Mutation (SNP) | VAF 119/313 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.131); catalogued as COSV65621705, COSV65623112; called by muse, mutect2, varscan2
- ZFHX4 | c.7807C>A p.H2603N | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.789); catalogued as rs200717354; called by muse, mutect2, varscan2
- ZFP64 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1474520863, COSV99403244; called by muse, mutect2, varscan2
- ZNF14 | c.1505C>A p.P502H | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV59850715; called by muse, mutect2, varscan2
- ZNF391 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 77/283 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs770350591, COSV55124355, COSV99772531; called by muse, mutect2, varscan2
- ZNF440 | c.1457A>G p.Y486C | Missense Mutation (SNP) | VAF 59/276 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs776157031; called by muse, mutect2, varscan2
- ZNF768 | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as COSV63322134; called by muse, mutect2, varscan2
- AC024940.1 | n.4086G>A | Splice Region (SNP) | VAF 98/343 reads (29%) | called by muse, mutect2, varscan2
- AC136428.1 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ADGRE2 | c.1840T>A p.L614M | Missense Mutation (SNP) | VAF 85/373 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- AJM1 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- AKAP9 | c.7124A>T p.Q2375L (on ENST00000359028; = p.Q2351L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/1046 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- AKR1E2 | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 116/311 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- AMER3 | c.2122C>G p.Q708E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AMIGO1 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 63/456 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANGPTL5 | c.1042C>A p.H348N | Missense Mutation (SNP) | VAF 139/889 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.1144A>G p.K382E | Missense Mutation (SNP) | VAF 66/628 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ANKRD34C | c.399T>A p.D133E | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ANKRD36 | c.883G>T p.G295* | Nonsense Mutation (SNP) | VAF 68/554 reads (12%) | called by muse, varscan2
- ANO4 | c.1606G>C p.A536P (on ENST00000392977 / NM_001286615.2; = p.A501P on NM_178826.4) | Missense Mutation (SNP) | VAF 96/457 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- AQP12A | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 119/282 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ARHGEF39 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by muse, mutect2
- BATF | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- C11orf94 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 59/378 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1R | c.46T>C p.W16R (on ENST00000536053 / NM_001354346.2; = p.W2R on NM_001733.7) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CACNA1I | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAPN11 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CBL | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 263/913 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCL3 | c.192C>G p.F64L | Missense Mutation (SNP) | VAF 95/684 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCT5 | c.993+8G>T | Splice Region (SNP) | VAF 169/1242 reads (14%) | called by muse, mutect2, varscan2
- CD1C | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR3 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP170 | c.3952G>T p.D1318Y | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CERCAM | c.1098C>A p.N366K | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.7689C>G p.D2563E | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP69 | c.1809T>A p.D603E | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- CIT | c.2338A>T p.R780W | Missense Mutation (SNP) | VAF 55/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COL22A1 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 86/636 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL4A5 | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 87/607 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CREB5 | c.210G>T p.E70D (on ENST00000357727 / NM_182898.4; = p.E63D on NM_004904.3) | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CREBBP | c.2430G>T p.M810I | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CRYBB3 | c.139A>T p.S47C | Missense Mutation (SNP) | VAF 135/607 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CTNND2 | c.2613G>C p.Q871H | Missense Mutation (SNP) | VAF 76/411 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYP3A43 | c.556G>C p.G186R | Missense Mutation (SNP) | VAF 32/455 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- DISP3 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- DLK1 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 47/832 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAAF2 | c.1238C>G p.T413S | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH5 | c.13272G>C p.M4424I | Missense Mutation (SNP) | VAF 82/1494 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- DNAH5 | c.13078G>A p.A4360T | Missense Mutation (SNP) | VAF 232/608 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DNAH6 | c.5198T>C p.V1733A | Missense Mutation (SNP) | VAF 100/393 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DPY19L2 | c.2045C>G p.A682G | Missense Mutation (SNP) | VAF 44/349 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- DPY19L2 | c.2044G>T p.A682S | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- DSCAM | c.3125C>A p.T1042N | Missense Mutation (SNP) | VAF 159/644 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- EML5 | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 163/472 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ENO4 | c.1060C>G p.Q354E (on ENST00000622726; = p.Q351E on NM_001242699.2) | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- FAAH2 | c.1424-1G>T p.X475_splice | Splice Site (SNP) | VAF 194/488 reads (40%) | called by muse, mutect2, varscan2
- FAM135B | c.1645C>A p.P549T | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FOXI3 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 48/561 reads (9%) | called by muse, mutect2
- FPR2 | c.829T>A p.Y277N | Missense Mutation (SNP) | VAF 96/491 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FREM2 | c.6994G>C p.E2332Q | Missense Mutation (SNP) | VAF 66/1040 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GGN | c.1229T>A p.L410Q | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GMEB1 | c.1217C>G p.S406* | Nonsense Mutation (SNP) | VAF 61/489 reads (12%) | called by muse, mutect2, varscan2
- GPR32 | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPRC6A | c.2105A>T p.Y702F | Missense Mutation (SNP) | VAF 215/654 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GSG1L | c.941C>A p.A314E (on ENST00000447459 / NM_001109763.2; = p.A159E on NM_144675.2) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HGF | c.238del p.L80Ffs*29 | Frame Shift Del (DEL) | VAF 125/600 reads (21%) | called by mutect2, pindel, varscan2
- HHIPL1 | c.248T>A p.L83Q | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- HSPA1L | c.1684G>T p.G562C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- IFNA21 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 182/764 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IGKV1D-37 | c.319A>T p.T107S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.271); called by mutect2, varscan2
- IRX3 | c.1254del p.G419Afs*104 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- KALRN | c.6056T>C p.V2019A (on ENST00000360013 / NM_001024660.4; = p.V322A on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 228/616 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNA1 | c.683G>T p.C228F | Missense Mutation (SNP) | VAF 114/526 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KIAA1522 | c.1474C>G p.P492A (on ENST00000373480 / NM_001198972.2; = p.P551A on NM_020888.3) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- KLHL10 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 88/301 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- LGALS13 | c.184G>C p.V62L | Missense Mutation (SNP) | VAF 212/1097 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- LIG1 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRMDA | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- LRP2 | c.6767A>C p.D2256A | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRRIQ1 | c.3779C>G p.S1260* | Nonsense Mutation (SNP) | VAF 40/1270 reads (3%) | called by muse, mutect2
- MAGEB10 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAGEL2 | c.3597G>T p.R1199S | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- MATN2 | c.246C>A p.D82E | Missense Mutation (SNP) | VAF 122/360 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MCF2 | c.700G>T p.V234F | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MCIDAS | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 108/326 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MMRN1 | c.2211T>G p.N737K | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- MOGAT2 | c.205del p.R69Gfs*15 | Frame Shift Del (DEL) | VAF 67/336 reads (20%) | called by mutect2, pindel, varscan2
- MRPS27 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTHFD2 | c.459T>G p.D153E | Missense Mutation (SNP) | VAF 95/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR4 | c.1784A>T p.Q595L | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MUC16 | c.11393T>A p.V3798D | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MUC17 | c.4861A>C p.M1621L | Missense Mutation (SNP) | VAF 30/1220 reads (2%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2
- MUC17 | c.6077C>A p.P2026H | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2
- MYO7A | c.1160G>T p.S387I | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NAPEPLD | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 136/1246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NBAS | c.2884G>T p.A962S | Missense Mutation (SNP) | VAF 138/548 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.877); called by muse, varscan2
- NEDD1 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2
- NEK11 | c.965A>T p.Q322L | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NLRP11 | c.2513del p.H838Lfs*17 | Frame Shift Del (DEL) | VAF 29/128 reads (23%) | called by mutect2, pindel, varscan2
- NOL7 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); called by muse, mutect2
- NRBP1 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 88/507 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- NWD2 | c.3178T>G p.Y1060D | Missense Mutation (SNP) | VAF 81/490 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- OBSCN | c.3193C>A p.L1065M | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OBSCN | c.21356C>T p.S7119L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10S1 | c.730A>T p.T244S | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR11L1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 116/642 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.043); called by muse, mutect2
- OR2A4 | c.27A>C p.R9S | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- OR4C11 | c.678C>A p.H226Q | Missense Mutation (SNP) | VAF 133/880 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- OR5AU1 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 106/414 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- OR5W2 | c.517_525del p.E173_N175del | In Frame Del (DEL) | VAF 31/215 reads (14%) | called by mutect2, pindel, varscan2
- OR8H1 | c.260C>A p.T87N | Missense Mutation (SNP) | VAF 130/600 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OTOGL | c.2098C>G p.Q700E (on ENST00000547103; = p.Q691E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 173/958 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PCDHB7 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 157/595 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); called by muse, varscan2
- PCNX2 | c.2621G>T p.C874F | Missense Mutation (SNP) | VAF 84/392 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PDE3A | c.2693G>T p.R898L | Missense Mutation (SNP) | VAF 157/838 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEAK1 | c.2360G>T p.G787V | Missense Mutation (SNP) | VAF 105/457 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PHACTR3 | c.1351G>T p.V451L | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PIK3CG | c.698T>C p.I233T | Missense Mutation (SNP) | VAF 88/819 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLA1A | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 239/685 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PLSCR2 | c.639G>C p.E213D (on ENST00000497985 / NM_001199978.1; = p.E140D on NM_020359.2) | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, mutect2
- PNMA5 | c.496G>C p.A166P | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLR3B | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 102/689 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- POTEI | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 72/1462 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); called by muse, mutect2
- PPDPFL | c.242C>A p.S81* | Nonsense Mutation (SNP) | VAF 120/903 reads (13%) | called by muse, mutect2, varscan2
- PPIP5K2 | c.1853G>T p.R618L | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PPP1R9B | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- PYHIN1 | c.73del p.V25Lfs*5 | Frame Shift Del (DEL) | VAF 22/184 reads (12%) | called by mutect2, pindel
- RAB11FIP5 | c.1016A>T p.N339I | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RCBTB1 | c.615G>T p.W205C | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REC114 | c.282G>C p.W94C | Missense Mutation (SNP) | VAF 55/722 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- REXO1 | c.3153G>T p.E1051D | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.014); called by muse, mutect2
- RFC1 | c.3116T>C p.M1039T (on ENST00000381897 / NM_001363496.2; = p.M1038T on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/628 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RNASEH2C | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- RSPH14 | c.199+1G>T p.X67_splice | Splice Site (SNP) | VAF 50/253 reads (20%) | called by muse, mutect2, varscan2
- RTF1 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 87/297 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SALL3 | c.2815G>T p.D939Y | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SAMD9L | c.4676G>A p.G1559D | Missense Mutation (SNP) | VAF 180/347 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SARAF | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCUBE1 | c.1333del p.E445Kfs*6 | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | called by mutect2, pindel, varscan2
- SH3TC2 | c.2669G>T p.W890L | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SH3TC2 | c.2668T>A p.W890R | Missense Mutation (SNP) | VAF 67/301 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHB | c.946G>C p.V316L | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SHROOM4 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.2629G>T p.E877* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.760+1G>C p.X254_splice | Splice Site (SNP) | VAF 40/247 reads (16%) | called by muse, mutect2, varscan2
- SLC2A1 | c.516+4A>G | Splice Region (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- SLC30A8 | c.533T>C p.M178T | Missense Mutation (SNP) | VAF 36/528 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC39A10 | c.470A>T p.K157I | Missense Mutation (SNP) | VAF 185/724 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- SPAG4 | c.303G>A p.S101= | Splice Region (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- STAB2 | c.7108-1G>C p.X2370_splice | Splice Site (SNP) | VAF 123/586 reads (21%) | called by muse, mutect2, varscan2
- SYCE1L | c.582-6C>A | Splice Region (SNP) | VAF 49/395 reads (12%) | called by muse, mutect2, varscan2
- SYCE1L | c.582-5C>A | Splice Region (SNP) | VAF 48/392 reads (12%) | called by muse, mutect2, varscan2
- SYNE1 | c.8223G>T p.R2741S (on ENST00000367255 / NM_182961.4; = p.R2748S on NM_033071.3) | Missense Mutation (SNP) | VAF 70/794 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SYNE1 | c.7972G>A p.D2658N (on ENST00000367255 / NM_182961.4; = p.D2665N on NM_033071.3) | Missense Mutation (SNP) | VAF 130/1005 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TAS2R41 | c.670C>G p.P224A | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TEX55 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 78/341 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- TFPI2 | c.312C>A p.D104E | Missense Mutation (SNP) | VAF 191/364 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TLR6 | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 84/544 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, varscan2
- TMEM200C | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- TMPRSS5 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 97/379 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.91685C>G p.P30562R (on ENST00000591111; = p.P23138R on NM_003319.4) | Missense Mutation (SNP) | VAF 210/630 reads (33%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.49274C>A p.P16425Q (on ENST00000591111; = p.P9001Q on NM_003319.4) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TWNK | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 228/469 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- USF3 | c.1131dup p.G378Wfs*33 | Frame Shift Ins (INS) | VAF 61/417 reads (15%) | called by mutect2, pindel, varscan2
- USP29 | c.1735C>G p.P579A | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VCAN | c.9902T>A p.V3301D | Missense Mutation (SNP) | VAF 107/516 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VWF | c.2776A>G p.T926A | Missense Mutation (SNP) | VAF 121/642 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- WDR97 | c.3331G>T p.E1111* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- XXYLT1 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ZBTB32 | c.1025-1G>A p.X342_splice | Splice Site (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- ZFHX3 | c.1364A>T p.K455M | Missense Mutation (SNP) | VAF 76/408 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZFP42 | c.851G>T p.R284M | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ZFP62 | c.1135G>C p.G379R (on ENST00000502412 / NM_001377944.1; = p.G346R on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ZNF311 | c.1640G>C p.R547T | Missense Mutation (SNP) | VAF 165/841 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF347 | c.634A>T p.K212* | Nonsense Mutation (SNP) | VAF 55/293 reads (19%) | called by muse, mutect2, varscan2
- ZNF43 | c.1013G>C p.G338A | Missense Mutation (SNP) | VAF 30/632 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- ZNF649 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 106/513 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ZNF653 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ZSCAN9 | c.767G>C p.C256S | Missense Mutation (SNP) | VAF 143/672 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZW10 | c.2011C>G p.L671V | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ADAMTS20 | c.633C>A p.T211= | Silent (SNP) | VAF 23/174 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.963G>A p.Q321= | Silent (SNP) | VAF 61/277 reads (22%) | catalogued as rs1443611958; called by muse, mutect2, varscan2
- ADGRA1 | c.282A>G p.T94= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- AFF2 | c.897G>A p.P299= | Silent (SNP) | VAF 17/429 reads (4%) | catalogued as rs200832993; called by muse, mutect2
- AHNAK2 | c.5211C>T p.F1737= | Silent (SNP) | VAF 34/552 reads (6%) | called by muse, mutect2
- AQP12A | c.261G>A p.Q87= | Silent (SNP) | VAF 119/282 reads (42%) | called by muse, mutect2, varscan2
- ARHGEF19 | c.1932C>T p.V644= | Silent (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- ARID1B | c.4017C>T p.P1339= | Silent (SNP) | VAF 67/406 reads (17%) | catalogued as COSV51667811; called by muse, mutect2, varscan2
- ASPH | c.1386G>T p.V462= | Silent (SNP) | VAF 85/335 reads (25%) | catalogued as COSV101063700; called by muse, mutect2, varscan2
- ASXL3 | c.150A>G p.P50= | Silent (SNP) | VAF 47/158 reads (30%) | called by muse, mutect2, varscan2
- BAZ2A | c.3594G>C p.G1198= | Silent (SNP) | VAF 157/653 reads (24%) | called by muse, mutect2, varscan2
- BRSK1 | c.279C>A p.V93= | Silent (SNP) | VAF 53/331 reads (16%) | called by muse, mutect2, varscan2
- C15orf39 | c.2259A>T p.P753= | Silent (SNP) | VAF 53/192 reads (28%) | called by muse, mutect2, varscan2
- CD163 | c.1587G>T p.G529= | Silent (SNP) | VAF 76/325 reads (23%) | called by muse, mutect2, varscan2
- CD1E | c.4C>T p.L2= | Silent (SNP) | VAF 45/213 reads (21%) | called by muse, mutect2, varscan2
- CDHR3 | c.1815C>A p.S605= | Silent (SNP) | VAF 18/250 reads (7%) | catalogued as rs1296890229; called by muse, mutect2
- CELSR2 | c.5028C>T p.S1676= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1309095439; called by muse, mutect2
- CEP76 | c.765A>C p.P255= | Silent (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- CR1 | c.354C>A p.I118= | Silent (SNP) | VAF 106/611 reads (17%) | called by muse, mutect2, varscan2
- CSMD3 | c.6825A>G p.P2275= (on ENST00000297405 / NM_001363185.1; = p.P2171= on NM_052900.3) | Silent (SNP) | VAF 106/911 reads (12%) | called by muse, mutect2, varscan2
- DEPDC5 | c.699A>G p.E233= | Silent (SNP) | VAF 34/243 reads (14%) | catalogued as rs1361700032; called by muse, mutect2, varscan2
- DERPC | c.1194T>C p.I398= | Silent (SNP) | VAF 27/128 reads (21%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1128C>T p.V376= | Silent (SNP) | VAF 25/198 reads (13%) | called by muse, mutect2, varscan2
- DLL3 | c.1353C>T p.L451= | Silent (SNP) | VAF 73/277 reads (26%) | catalogued as rs1415685121; called by muse, mutect2, varscan2
- DNAH14 | c.7056G>A p.V2352= (on ENST00000445597; = p.V3005= on NM_001367479.1) | Silent (SNP) | VAF 66/419 reads (16%) | called by muse, mutect2, varscan2
- DNAH2 | c.10830C>T p.C3610= | Silent (SNP) | VAF 75/191 reads (39%) | catalogued as rs143386308; called by muse, mutect2, varscan2
- EGR2 | c.1089C>T p.I363= | Silent (SNP) | VAF 27/444 reads (6%) | called by muse, mutect2
- ERICH3 | c.3801G>T p.V1267= | Silent (SNP) | VAF 77/695 reads (11%) | called by muse, mutect2, varscan2
- EVX2 | c.246G>T p.T82= | Silent (SNP) | VAF 236/603 reads (39%) | catalogued as rs746936014; called by muse, mutect2, varscan2
- FAR2 | c.102C>T p.S34= | Silent (SNP) | VAF 41/634 reads (6%) | called by muse, mutect2
- GABRB2 | c.624A>T p.P208= | Silent (SNP) | VAF 78/498 reads (16%) | called by muse, mutect2, varscan2
- GLYAT | c.795A>G p.V265= | Silent (SNP) | VAF 68/428 reads (16%) | called by muse, mutect2, varscan2
- GRIK1 | c.582C>A p.S194= | Silent (SNP) | VAF 67/283 reads (24%) | called by muse, mutect2, varscan2
- HIF3A | c.1018T>C p.L340= (on ENST00000377670 / NM_152795.4; = p.L271= on NM_022462.4) | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- HIVEP2 | c.2511T>C p.C837= | Silent (SNP) | VAF 86/431 reads (20%) | called by muse, mutect2, varscan2
- HOXA3 | c.285C>A p.P95= | Silent (SNP) | VAF 47/66 reads (71%) | called by muse, mutect2, varscan2
- HOXB2 | c.249G>C p.P83= | Silent (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- IL5RA | c.786G>T p.V262= | Silent (SNP) | VAF 142/492 reads (29%) | called by muse, mutect2, varscan2
- IPMK | c.1053G>A p.Q351= | Silent (SNP) | VAF 24/772 reads (3%) | called by muse, mutect2
- IRS2 | c.3666G>T p.P1222= | Silent (SNP) | VAF 70/190 reads (37%) | called by muse, varscan2
- ITGA8 | c.2544C>T p.A848= | Silent (SNP) | VAF 113/465 reads (24%) | catalogued as COSV100958917, COSV65226779; called by muse, mutect2, varscan2
- ITM2A | c.189C>A p.I63= | Silent (SNP) | VAF 83/251 reads (33%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.63G>A p.L21= | Silent (SNP) | VAF 92/225 reads (41%) | catalogued as rs1274820580; called by muse, mutect2, varscan2
- JARID2 | c.1599G>T p.V533= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- KCNAB1 | c.165C>A p.L55= | Silent (SNP) | VAF 102/967 reads (11%) | catalogued as COSV101050731; called by muse, mutect2, varscan2
- KIAA0319 | c.378C>A p.P126= | Silent (SNP) | VAF 55/180 reads (31%) | catalogued as rs763722667; called by muse, mutect2, varscan2
- KIF27 | c.984C>A p.S328= | Silent (SNP) | VAF 43/150 reads (29%) | called by muse, mutect2, varscan2
- LAMC3 | c.2764C>T p.L922= | Silent (SNP) | VAF 60/190 reads (32%) | catalogued as rs753740635; called by muse, mutect2, varscan2
- LCE5A | c.279C>A p.G93= | Silent (SNP) | VAF 67/269 reads (25%) | called by muse, mutect2, varscan2
- LILRA1 | c.267C>A p.T89= | Silent (SNP) | VAF 68/488 reads (14%) | called by muse, varscan2
- LRPPRC | c.813C>G p.L271= | Silent (SNP) | VAF 121/779 reads (16%) | called by muse, mutect2, varscan2
- LRRTM3 | c.90C>A p.A30= | Silent (SNP) | VAF 72/271 reads (27%) | catalogued as COSV63669457; called by muse, mutect2, varscan2
- LYAR | c.15A>T p.T5= | Silent (SNP) | VAF 26/201 reads (13%) | called by muse, mutect2, varscan2
- MEGF6 | c.2628C>T p.S876= | Silent (SNP) | VAF 26/163 reads (16%) | catalogued as rs1412853886; called by muse, mutect2, varscan2
- MEI1 | c.1599C>T p.S533= | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as rs202048478; called by muse, mutect2, varscan2
- MYH6 | c.1254G>A p.V418= | Silent (SNP) | VAF 66/588 reads (11%) | catalogued as rs1433770124; called by muse, mutect2, varscan2
- MYL10 | c.555C>A p.T185= | Silent (SNP) | VAF 320/591 reads (54%) | catalogued as COSV56209340; called by muse, mutect2, varscan2
- MYO15A | c.414A>T p.T138= | Silent (SNP) | VAF 29/228 reads (13%) | called by muse, mutect2, varscan2
- MYO7B | c.2685C>G p.G895= | Silent (SNP) | VAF 35/123 reads (28%) | called by muse, mutect2, varscan2
- NFYA | c.366G>T p.V122= | Silent (SNP) | VAF 71/503 reads (14%) | called by muse, mutect2, varscan2
- NLRP7 | c.2103T>A p.R701= (on ENST00000340844 / NM_206828.3; = p.R673= on NM_139176.3) | Silent (SNP) | VAF 87/524 reads (17%) | called by muse, mutect2, varscan2
- NPHS1 | c.2241C>T p.D747= | Silent (SNP) | VAF 39/148 reads (26%) | called by muse, mutect2, varscan2
- NR0B2 | c.507G>C p.L169= | Silent (SNP) | VAF 60/215 reads (28%) | catalogued as COSV99575018; called by muse, mutect2, varscan2
- NUF2 | c.993G>A p.L331= | Silent (SNP) | VAF 41/150 reads (27%) | called by muse, mutect2, varscan2
- OCM | c.273T>C p.D91= | Silent (SNP) | VAF 20/544 reads (4%) | called by muse, mutect2
- OR14A2 | c.342T>A p.T114= | Silent (SNP) | VAF 96/550 reads (17%) | called by muse, mutect2, varscan2
- OR51D1 | c.561C>A p.V187= | Silent (SNP) | VAF 82/502 reads (16%) | called by muse, mutect2, varscan2
- OR5H6 | c.153T>C p.Y51= (on ENST00000642105; = p.Y35= on NM_001005479.2) | Silent (SNP) | VAF 92/643 reads (14%) | catalogued as COSV67350953; called by muse, mutect2, varscan2
- OR5M10 | c.99G>C p.A33= | Silent (SNP) | VAF 237/990 reads (24%) | catalogued as rs781228134, COSV73242255; called by muse, mutect2, varscan2
- OR5T1 | c.427C>T p.L143= | Silent (SNP) | VAF 95/446 reads (21%) | catalogued as rs367855114; called by muse, mutect2, varscan2
- OSBP2 | c.537A>G p.L179= | Silent (SNP) | VAF 75/321 reads (23%) | called by muse, mutect2, varscan2
- OTX1 | c.759G>A p.A253= | Silent (SNP) | VAF 100/532 reads (19%) | catalogued as rs541502870, COSV56995851; called by muse, mutect2, varscan2
- PAPPA2 | c.1053C>T p.T351= | Silent (SNP) | VAF 142/769 reads (18%) | called by muse, mutect2, varscan2
- PCDH17 | c.1869C>G p.L623= | Silent (SNP) | VAF 82/248 reads (33%) | catalogued as COSV64973371; called by muse, mutect2, varscan2
- PEX6 | c.2205G>T p.L735= | Silent (SNP) | VAF 105/441 reads (24%) | called by muse, mutect2, varscan2
- PMFBP1 | c.2070C>G p.T690= (on ENST00000537465; = p.T685= on NM_031293.3) | Silent (SNP) | VAF 109/668 reads (16%) | catalogued as COSV52825557; called by muse, mutect2, varscan2
- PRAMEF11 | c.120A>C p.P40= | Silent (SNP) | VAF 112/551 reads (20%) | catalogued as rs748236916, COSV71306358; called by muse, mutect2, varscan2
- RAI14 | c.2826C>T p.V942= | Silent (SNP) | VAF 55/368 reads (15%) | called by muse, mutect2, varscan2
- RBM4 | c.327C>T p.I109= | Silent (SNP) | VAF 61/336 reads (18%) | catalogued as COSV100029547, COSV59519455; called by muse, mutect2, varscan2
- RPN1 | c.15C>T p.A5= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs919717895; called by muse, mutect2, varscan2
- RREB1 | c.4302G>T p.G1434= | Silent (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- SCG3 | c.24T>A p.T8= | Silent (SNP) | VAF 97/396 reads (24%) | called by muse, mutect2, varscan2
- SDS | c.393C>A p.V131= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- SLC17A6 | c.72C>A p.L24= | Silent (SNP) | VAF 34/222 reads (15%) | called by muse, mutect2, varscan2
- SLC25A23 | c.990G>T p.G330= | Silent (SNP) | VAF 33/230 reads (14%) | called by muse, mutect2, varscan2
- SLC34A3 | c.1203C>A p.P401= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs1378863618; called by muse, mutect2, varscan2
- SNCAIP | c.318G>A p.Q106= | Silent (SNP) | VAF 69/255 reads (27%) | called by muse, mutect2, varscan2
- SOX11 | c.1323T>C p.Y441= | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2
- SPTBN4 | c.3375G>A p.A1125= | Silent (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- SUPT20HL1 | c.2292G>T p.V764= | Silent (SNP) | VAF 56/144 reads (39%) | called by muse, mutect2, varscan2
- SYNE1 | c.11742C>G p.V3914= | Silent (SNP) | VAF 99/1157 reads (9%) | called by muse, mutect2
- TAF1L | c.1152C>A p.G384= | Silent (SNP) | VAF 150/652 reads (23%) | called by muse, mutect2, varscan2
- TINAG | c.1104C>T p.I368= | Silent (SNP) | VAF 78/447 reads (17%) | called by muse, mutect2, varscan2
- TMEM177 | c.324C>T p.A108= | Silent (SNP) | VAF 97/254 reads (38%) | called by muse, mutect2, varscan2
- TPTE2 | c.249G>T p.L83= (on ENST00000400230 / NM_199254.2; = p.L46= on NM_130785.3) | Silent (SNP) | VAF 37/240 reads (15%) | called by muse, varscan2
- TUFT1 | c.744G>T p.A248= | Silent (SNP) | VAF 67/293 reads (23%) | called by muse, mutect2, varscan2
- WDFY4 | c.3087G>T p.V1029= | Silent (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- ZBED4 | c.990C>T p.H330= | Silent (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- ZNF148 | c.1848T>C p.T616= | Silent (SNP) | VAF 42/443 reads (9%) | called by muse, mutect2
- ZNF571 | c.24C>T p.F8= | Silent (SNP) | VAF 80/490 reads (16%) | called by muse, varscan2
- ZNF7 | c.1368T>A p.L456= | Silent (SNP) | VAF 86/476 reads (18%) | called by muse, mutect2, varscan2
- ZNF99 | c.112A>C p.R38= | Silent (SNP) | VAF 89/529 reads (17%) | catalogued as COSV101233991; called by muse, mutect2, varscan2
- AC011487.2 | n.1100C>A | RNA (SNP) | VAF 58/208 reads (28%) | called by muse, mutect2, varscan2
- AC022182.2 | n.173C>A | RNA (SNP) | VAF 61/174 reads (35%) | called by muse, mutect2, varscan2
- AC073348.1 | n.141T>A | RNA (SNP) | VAF 112/472 reads (24%) | called by muse, mutect2, varscan2
- ACTG1 | c.*13G>T | 3'UTR (SNP) | VAF 112/457 reads (25%) | called by muse, mutect2, varscan2
- AGXT2 | chr5:35049167 A>T | 5'Flank (SNP) | VAF 64/497 reads (13%) | catalogued as rs750736912, COSV51487773; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825409 C>G | 5'Flank (SNP) | VAF 9/198 reads (5%) | called by muse, mutect2
- AP000769.5 | chr11:65499628 G>A | 5'Flank (SNP) | VAF 64/304 reads (21%) | called by muse, varscan2
- AP000769.5 | chr11:65499699 G>C | 5'Flank (SNP) | VAF 52/258 reads (20%) | called by muse, varscan2
- AQP4 | c.*18A>T | 3'UTR (SNP) | VAF 138/601 reads (23%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+39431A>C | Intron (SNP) | VAF 162/699 reads (23%) | called by muse, mutect2, varscan2
- COL6A4P1 | n.604G>A | RNA (SNP) | VAF 18/151 reads (12%) | catalogued as rs760869213; called by muse, mutect2
- CSMD3 | c.*26del | 3'UTR (DEL) | VAF 165/629 reads (26%) | called by mutect2, pindel, varscan2
- CSMD3 | c.178+59968C>G | Intron (SNP) | VAF 286/859 reads (33%) | catalogued as COSV52330392; called by muse, mutect2, varscan2
- DARS2 | c.396+44A>C | Intron (SNP) | VAF 98/450 reads (22%) | called by muse, mutect2, varscan2
- DCP1B | c.320-3247A>T | Intron (SNP) | VAF 95/538 reads (18%) | called by muse, mutect2, varscan2
- DENND10P1 | n.321C>A | RNA (SNP) | VAF 184/564 reads (33%) | called by muse, mutect2, varscan2
- ECPAS | c.22+9C>T | Intron (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- EDN3 | c.-34C>T | 5'UTR (SNP) | VAF 56/205 reads (27%) | catalogued as rs748531162, COSV100285173, COSV61110199; called by muse, mutect2, varscan2
- EPB41L2 | c.2044-210G>A | Intron (SNP) | VAF 98/744 reads (13%) | called by muse, mutect2, varscan2
- ERG | c.766+69C>G | Intron (SNP) | VAF 168/617 reads (27%) | called by muse, mutect2, varscan2
- FAM90A27P | n.128C>G | RNA (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2
- FGF8 | c.69+98C>T | Intron (SNP) | VAF 34/58 reads (59%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-2616G>A | Intron (SNP) | VAF 11/329 reads (3%) | called by muse, mutect2
- GAMT | c.570+148A>G | Intron (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- GSPT1 | c.-63+347G>A | Intron (SNP) | VAF 58/172 reads (34%) | called by muse, varscan2
- IGFN1 | c.1241+201C>A | Intron (SNP) | VAF 48/201 reads (24%) | called by muse, mutect2, varscan2
- IL10RA | c.-68A>T | 5'UTR (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- KCP | c.2155+28G>C | Intron (SNP) | VAF 69/192 reads (36%) | catalogued as rs761399028; called by muse, mutect2, varscan2
- L1CAM | c.3458-48G>A | Intron (SNP) | VAF 54/103 reads (52%) | catalogued as rs200396267; called by muse, mutect2, varscan2
- MACROH2A1 | c.954-2851G>T | Intron (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- MANBA | c.1455+24G>A | Intron (SNP) | VAF 141/557 reads (25%) | called by muse, mutect2, varscan2
- NIBAN3 | c.1539+21G>T | Intron (SNP) | VAF 52/216 reads (24%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-109838G>T | Intron (SNP) | VAF 155/555 reads (28%) | catalogued as COSV58456353; called by muse, mutect2, varscan2
- OR2M1P | n.558C>G | RNA (SNP) | VAF 88/438 reads (20%) | called by muse, mutect2, varscan2
- PIPSL | n.1789C>A | RNA (SNP) | VAF 395/814 reads (49%) | called by muse, mutect2, varscan2
- PLEKHM1P1 | n.2329A>G | RNA (SNP) | VAF 106/339 reads (31%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.330+135A>T | Intron (SNP) | VAF 16/286 reads (6%) | called by muse, mutect2
- PTPRR | c.*2T>A | 3'UTR (SNP) | VAF 70/312 reads (22%) | called by muse, varscan2
- REG1B | c.433+66G>T | Intron (SNP) | VAF 72/273 reads (26%) | called by muse, mutect2, varscan2
- RGPD1 | c.48+5890C>G | Intron (SNP) | VAF 71/392 reads (18%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.109-865C>T | Intron (SNP) | VAF 32/266 reads (12%) | called by muse, mutect2, varscan2
- SDHAP1 | n.1255G>A | RNA (SNP) | VAF 32/838 reads (4%) | called by muse, mutect2
- SLC7A5 | c.*32G>A | 3'UTR (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
- SNORD115-16 | n.79G>T | RNA (SNP) | VAF 140/473 reads (30%) | catalogued as rs1242973379; called by muse, mutect2, varscan2
- SPATA31D5P | n.946C>A | RNA (SNP) | VAF 120/472 reads (25%) | called by muse, mutect2, varscan2
- SZRD1 | c.52-3771T>C | Intron (SNP) | VAF 66/712 reads (9%) | called by muse, mutect2
- TEAD4 | c.355-332G>A | Intron (SNP) | VAF 28/118 reads (24%) | called by muse, mutect2, varscan2
- UGT2B27P | n.194G>T | RNA (SNP) | VAF 67/859 reads (8%) | called by muse, mutect2
- UXS1 | c.1028-408G>T | Intron (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- VIM | c.*43T>C | 3'UTR (SNP) | VAF 36/378 reads (10%) | catalogued as rs760635500; called by muse, mutect2
- ZBTB49 | c.*9G>T | 3'UTR (SNP) | VAF 37/259 reads (14%) | catalogued as COSV61925966; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451265 C>T | 5'Flank (SNP) | VAF 59/296 reads (20%) | called by muse, mutect2, varscan2
